Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A936, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A936-01A (Primary Tumor).

[page 1 of 5]
Patient Name

MRN:

DOB

Gender:F

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Surgical Pathology Consultation Report

* Addeded *

SPECIMEN(S) RECEIVED

1. Mediastinum: Aortic Adventitia- query thymoma- for quick section
2. Thymus: & mediastinal tumour, portion of rt lung- long stitch marks L superior pole

DIAGNOSIS

1. Soft tissue (aortic adventitia), biopsy:
- Negative for malignancy.
2. Thymus with portion of adhered pericardium and right lung:
- a) Thymic carcinoma, favor poorly differentiated squamous cell carcinoma, pT2aN0 (See comment) with:
- i) Maximum tumour dimension: 7.1 cm
- ii) Focal areas of transcapsular penetration into immediately adjacent mediastinal soft tissue
- iii) No invasion of either adhered pericardium or lung
- iv) Margins of resection: No tumor involvement
- b) Peri-thymic lymph nodes (19 examined): Negative for malignancy
- c) Native thymus: Involutional changes consistent with patient's age
- d) Right lung tissue: No significant pathology

ICD 8-3
Thymus, Carcinoma NOS 8586/3
Site: Thymus C37.9
JW 4/2/14

COMMENT

2. Sections show a more or less encapsulated tumor composed of lobules of relatively cohesive pleomorphic polygonal to spindle-form epithelial cells with large vesicular nuclei exhibiting irregularly clumped chromatin and prominent nucleoli. Mitotic figures are readily evident (approximately 10/10 HPFs) as is cell necrosis. The tumor cells stain strongly positive for AE1:AE3 cytokeratin, CK5, p63 and CD5 with focal staining for Cam
- 5.2. Between the tumor lobules and to a varying extent infiltrating the tumor mature T and B cells are

[page 2 of 5]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender:F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

evident (CD3/CD5 and CD20 positive respectively) with occasional plasma cells. Lymphoid follicle formation is also evident. Immature T-cells are not seen (CD1a stains only dendritic cells; CD99 apparent staining of some cells is of questionable significance). This staining profile of the malignant epithelial cells together with the background population of lymphocytes which are of a reactive nature (as opposed to being immature T-cells) indicate a diagnosis of thymic carcinoma rather than a thymoma.

In focal areas the tumor does extend through the capsule into immediately adjacent mediastinal soft tissue but the margins of resection appear to be clear.

In terms of behavior I would expect this tumor to be locally aggressive (as already evidenced by the for-going) and to be associated with a high incidence of intra-thoracic recurrence.

SYNOPTIC DATA

Tumor Site:	Thymus structure
Specimen:	Thymus and other: portion of right lung
Procedure:	Thymectomy
Specimen Integrity:	Intact
Specimen Weight:	166.4 g
Histologic Type:	Squamous cell carcinoma
Tumor Size:	Greatest dimension: 7.1 cm Additional dimension: 6.5 cm Additional dimension: 4.2 cm
Tumor Extension:	Not identified: .
Margins:	Margins uninvolved by tumor
Treatment Effect:	Not applicable: .
Lymph-Vascular Invasion:	Not identified: .
Regional Lymph Nodes:	No regional lymph node metastases Number of lymph nodes examined: 19 Number of lymph nodes involved: 0
Primary Tumor (pT):	pT2: Tumor invades pericapsular connective tissue
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastases
Distant Metastasis (pM):	Distant metastasis not applicable (.)
Additional Pathologic Findings:	Age-appropriate involution changes Cystic changes in adjacent thymus

[page 3 of 5]
Department of Pathology

Patient Name:

MRN:

Service:

Collected:

DOB:

Visit #:

Resulted:

Gender:F

Location:

Facility:

Ordering MD:

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen is labeled with the patient's identification and as "aortic adventitia, query thymoma, QS". It consists of one piece of tissue measuring 0.9 x 0.6 x 0.1 cm. It is submitted in toto for frozen section and resubmitted in block 1A.
2. The specimen is labeled with the patient's identification and as "thymus and mediastinal tumor and portion right lung long stitch marks left superior pole". It consists of an oriented resection containing thymus / peri-thymic adipose tissue and a tumour mass inferiorly with an attached portion of right lung. The specimen weighs 166.4-g (unfixed) and has overall dimensions of 16 cm SI x 8.5 cm ML x 4.9 cm AP. The uninvolved portion of thymus and peri-thymic adipose tissue (superior to tumour) measures 5.3 cm SI x 4.9 cm ML x 1.0 cm AP. The tumor measures 6.5 cm SI x 7.1 cm ML x 4.2 cm AP. The tumour is encapsulated and mostly well-circumscribed, although the interface with the peri-thymic adipose tissue is slightly irregular and lobulated. The tumour has a white-tan, homogenous, firm cut surface without necrosis or hemorrhagic areas grossly. A portion of presumed pericardium (3.5 cm x 0.5 cm) is attached to the posterior aspect of the tumour. It has a smooth surface and is mobile over the tumour. The right lung wedge resection attached to the lateral aspect of the mass measures 7.0 cm SI x 7.5 cm ML x 1.4 cm AP and has stapled parenchymal resection margins measuring 5.5 cm, 5.0 cm and 4.5 cm. The tumour focally abuts the lung parenchyma and most of the interface is well-delineated. The tumour is located approximately 1.8 cm from the closest lung parenchyma resection margin and 0.5 cm from the presumed pericardial margin. Multiple possible lymph nodes ranging from 0.3 cm to 1.8 cm in greatest dimension are identified in the peri-thymic adipose tissue. The surface of the specimen is marked with silver nitrate.

Representative sections submitted as follows:

2A-B tumour with pericardium

2C-G tumour with thymus and peri-thymic adipose tissue

Status: supplemental

Page: 3 of 5

[page 4 of 5]
Department of Pathology

Patient Name

MRN:

Service:

Collected:

DOB:

Visit #:

Resulted:

Gender: F

Location:

Facility:

Ordering MD:

(two possible lymph nodes in 2E; two possible lymph nodes, bisected, in 2F-G)

2H-I tumour with capsule

2J tumour with lung

2K-L two possible lymph nodes, serially sectioned (same lymph nodes as in block 2E)

2M possible uninvolved thymus

2N-O lung parenchyma resection margins, en face

2P possible tumour and superior soft tissue

2Q two possible lymph nodes, bisected

2R-S one possible lymph node each, bisected

2T-U multiple possible lymph nodes

QUICK SECTION

1. Mediastinum: Aortic Adventitia- query thymoma- for quick section:
Fibrous tissue and inflammation
Negative for tumor

Addendum Status: Signed Out
Date Reported:

Addendum Diagnosis

2. Thymic carcinoma, favor poorly-differentiated squamous cell carcinoma.
See original report and this addendum comment.

Addendum Comment

Following completion of this case I have received further immunostains: these show positive staining for both chromogranin and synaptophysin therefore indicating a component of neuroendocrine differentiation in what otherwise is considered to be a poorly-differentiated squamous cell carcinoma. The finding of neuroendocrine differentiation in is well known, for example up to 20% of pulmonary squamous cell carcinomas will

Status: supplemental

Page: 4 of 5

[page 5 of 5]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

show neuroendocrine differentiation with immunostaining. However, the significance of this finding in terms of prognosis and treatment is unknown and the general view is that it should be disregarded to all practical purposes. Similarly in the context of neoplasms of the thymus, I think that the finding of neuroendocrine differentiation, while interesting, is likely of no real clinical significance.

Status: supplemental

Source: NCI Genomic Data Commons file 1c188714-6fa7-4bae-849d-1805e5778b80 (TCGA-XU-A936.86268FD0-9AB5-4F45-9458-D95510C321D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).